Somatic mutation profile of tumor specimen TARGET-10-PARGHW-04A (aliquot TARGET-10-PARGHW-04A-01D) from TARGET case TARGET-10-PARGHW, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 18.7 years (6,842 days).
Specimen TARGET-10-PARGHW-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eb086c65-5075-4de9-9300-a4954a1d4c0f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARGHW-10A (Blood Derived Normal), aliquot TARGET-10-PARGHW-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2c46286c-6a57-4b61-b892-1fd3a0a81588

The open-access MAF lists 22 somatic variants for this specimen: 21 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 15, Nonsense Mutation 2, Frame Shift Ins 2, Silent 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- USH2A | c.8740C>T p.R2914* | Nonsense Mutation (SNP) | VAF 107/263 reads (41%) | catalogued as rs766590491, CM104087, COSV56424805; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC9 | c.3782A>G p.Y1261C | Missense Mutation (SNP) | VAF 114/222 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV53983843; called by muse, mutect2, varscan2
- ANKRD24 | c.1204C>T p.R402W | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs377087098; called by muse, mutect2, varscan2
- CAD | c.4981C>T p.R1661W | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs774531248, COSV53031228; called by muse, mutect2, varscan2
- DIAPH2 | c.990G>C p.M330I | Missense Mutation (SNP) | VAF 46/267 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV61289537; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.928G>A p.V310I | Missense Mutation (SNP) | VAF 174/393 reads (44%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.664); catalogued as rs1280843038, COSV50053088; called by muse, mutect2, varscan2
- ECPAS | c.2390A>G p.D797G | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.044); catalogued as rs776454890, COSV52200772; called by muse, mutect2, varscan2
- FGFBP2 | c.460G>C p.A154P | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.679); catalogued as COSV52588515; called by muse, mutect2, varscan2
- GDF7 | c.533C>T p.P178L | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.67); PolyPhen benign (0.039); catalogued as rs1019448206, COSV55348545; called by muse, mutect2, varscan2
- GLT1D1 | c.152T>C p.I51T | Missense Mutation (SNP) | VAF 146/365 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.017); catalogued as COSV55886982; called by muse, varscan2
- H2AC17 | c.44C>G p.A15G | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.078); catalogued as COSV58153871; called by muse, mutect2, varscan2
- KIAA1217 | c.5180C>A p.P1727H | Missense Mutation (SNP) | VAF 57/175 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as rs1270811788, COSV100287248, COSV56822414; called by muse, mutect2, varscan2
- MDGA2 | c.1340G>A p.R447H (on ENST00000399232 / NM_001113498.2; = p.R149H on NM_182830.4) | Missense Mutation (SNP) | VAF 98/210 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs866090116, COSV62078847; called by muse, mutect2, varscan2
- NLRP10 | c.1216C>T p.R406W | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as rs1442127677, COSV60782149; called by muse, mutect2, varscan2
- SAMD15 | c.1019A>T p.E340V | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.046); catalogued as COSV53627819; called by muse, mutect2, varscan2
- STMN2 | c.526G>T p.E176* | Nonsense Mutation (SNP) | VAF 122/250 reads (49%) | catalogued as COSV55222009; called by muse, mutect2, varscan2
- TEP1 | c.6603A>T p.A2201= | Splice Region (SNP) | VAF 58/135 reads (43%) | catalogued as COSV52998970; called by muse, mutect2, varscan2
- TSEN2 | c.224G>C p.R75P | Missense Mutation (SNP) | VAF 149/366 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53190690; called by muse, mutect2, varscan2
- BCORL1 | c.5014_5015dup p.G1673Lfs*29 | Frame Shift Ins (INS) | VAF 12/14 reads (86%) | called by mutect2, varscan2
- TRAJ28 | c.1del p.Y2Tfs*? | Frame Shift Del (DEL) | VAF 152/421 reads (36%) | called by mutect2, pindel*, varscan2
- UBTF | c.1300_1301insGGGAA p.E434Gfs*6 | Frame Shift Ins (INS) | VAF 14/26 reads (54%) | called by mutect2, varscan2*
- HMCN1 | c.9252C>T p.N3084= | Silent (SNP) | VAF 89/204 reads (44%) | catalogued as rs764091385, COSV54878501; called by muse, mutect2, varscan2
